Surgical pathology report (de-identified scan), TCGA case TCGA-CS-5395, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-5395-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Right parietal primary tumor: GLIAL NEOPLASM WITH OLIGODENDROCYTIC FEATURES AND ELEVATED PROLIFERATION INDEX, SEE MICROSCOPIC DESCRIPTION, SEE NOTE
2. Right parietal: GLIAL NEOPLASM WITH OLIGODENDROCYTIC FEATURES AND ELEVATED PROLIFERATION INDEX, SEE MICROSCOPIC DESCRIPTION, SEE NOTE

Comment:

While many of areas of this tumor demonstrate features of an oligodendroglioma, there is no area demonstrating the classic tightly packed, honeycomb-like architecture of an oligodendroglioma with numerous perinuclear halos. In addition, perinuclear halos are relatively rare in this tumor. This may be due to the fact that all of the tissue was frozen and therefore the classic morphology may have been disrupted. As a result, a definitive diagnosis of oligodendroglioma cannot be made reliably. If this tumor were an astrocytoma, the presence of mitoses would require a diagnosis of an anaplastic astrocytoma, grade III (WHO scale). However, if this were an oligodendroglioma, the presence of mitoses would lead to a diagnosis of oligodendroglioma, grade II (WHO scale). In any case, the proliferation index is relatively high for a grade II oligodendroglioma. In fact, oligodendrogliomas with proliferation indices of greater than 5% are associated with a significantly poorer prognosis than those with proliferation indices less than 5% (1). Therefore, regardless of lineage, this tumor is likely to behave more aggressively than a typical grade II oligodendroglioma. Genetic analysis for the 1p, 19q deletion seen in many prognostically favorable oligodendroglial tumors is pending and when completed, a separate report will be issued.

[page 2 of 4]
[REDACTED]

[REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor consists of an infiltrative and moderately pleomorphic proliferation of glial cells with relatively round nuclei. In some areas, there are perinuclear halos. There is a fine capillary network that in some areas displays a chicken-wire pattern. Scattered mitoses are present, however, there is no endothelial proliferation or necrosis. Immunohistochemistry for the proliferation antigen Ki67 was performed as follows: Nine 250 x 250 micron fields were counted and the percentage of labeled nuclei determined. More than 1,000 cells were counted. The proliferation index ranged from 10.5% to 18.4% with an overall average of 13.6%.

Frozen Section Diagnosis:

1. Right parietal primary tumor: Favor glial neoplasm. Severe freezing artifact. Final deferred.
2. Right parietal: Consistent with glial neoplasm. No anaplastic features on frozen section.

Clinical History and Diagnosis:

Right parietal primary tumor

[page 3 of 4]
Source of Specimen:

- 1: Right parietal primary tumor
- 2: Right parietal

1. Right parietal primary tumor: Received fresh in a specimen container labeled with the patient's name and "right parietal primary tumor" are two fragments of white-tan soft tissue measuring 1 x 0.8 x 0.3 cm and 0.8 x 0.6 x 0.3 cm. Frozen sections are prepared and the entire specimen is submitted for permanent section in one cassette. (There is no frozen section control as the block was exhausted in frozen section preparation).

2. Right parietal: Received fresh for frozen section in a specimen container labeled with the patient's name are 3 fragments of tan-pink soft tissue measuring 0.8 x 0.4 x 0.3 cm in aggregate. Frozen sections are prepared and the entire specimen is submitted for permanent section in two cassettes as follows:

- A. frozen section control
- B. remainder of specimen

Histology Laboratory

H&E

Part 1: Right parietal primary tumor

RECUT

UNSTAINED

[page 4 of 4]
[REDACTED]

[REDACTED]

IMMUNOPATHOLOGY REPORT

EVALUATION:

Immunohistochemistry for the proliferation antigen Ki67 was performed as follows: Nine 250 x 250 micron fields were counted and the percentage of labeled nuclei determined. More than 1,000 cells were counted. The proliferation index ranged from 10.5% to 18.4% with an overall average of 13.6%.

[REDACTED]

[REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Source: NCI Genomic Data Commons file 0bdf9ec5-0a00-428a-8ba7-d1e46f760a62 (TCGA-CS-5395.509C2DA8-C6CF-4803-A643-E42AD2E4D1F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).